TCGA case TCGA-AA-3672 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c46971a1-cbac-425d-bac2-f4142c92522e

Demographics
Sex at birth: female; Country of residence at enrollment: Germany; Age: 90 years or older (exact value withheld by GDC); Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.4; Tissue or organ of origin: Transverse colon; Site of resection or biopsy: Transverse colon; Classification of tumor: primary; Age at diagnosis: 90 years or older (exact value withheld by GDC); Year of diagnosis: 2006; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 0 days.
   Pathology details: Lymph nodes positive: 4; Lymph nodes tested: 21; Lymphatic invasion present: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the breast (histology not recorded by GDC). AJCC pathologic T: T2.
   Treatment given: Treatment type: Hormone Therapy.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor.
- Days to follow up: 0 days; Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 1.27 ng/mL.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AA-3672-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.8.
  Slide TCGA-AA-3672-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 2; Percent necrosis: 5; Percent stromal cells: 8.
  Slide TCGA-AA-3672-01A-01-TS1: Section location: Top; Percent tumor cells: 86; Percent tumor nuclei: 85; Percent normal cells: 3; Percent necrosis: 3; Percent stromal cells: 8.
- Sample TCGA-AA-3672-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AA-3672-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 1.27; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Mismatch rep proteins tested by IHC: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast; Other malignancy histological type: Malignant neoplasm of Breast.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -1188.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Prior malignancy breast cancer treated with unknown hormone therapy.
- Prior malignancy: Prior malignancy breast cancer treated with unknown hormone therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 28 days; disease-specific survival: no event (censored), 28 days; progression-free interval: no event (censored), 28 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-AA-3672-01): tumor purity 0.69, ploidy 2.05, whole-genome doublings 0 (call status: legacy_call).
